CPTAC case C3L-03513 — Pancreas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/85e4b395-dde7-49c4-92c3-47d168cfb390

Demographics
Sex at birth: female; Year of birth: 1950; Country of birth: United States.

Other clinical attributes
- Weight: 112.5 kg; Height: 162 cm; BMI: 42.87.

Biospecimens (1 sample)
- Sample C3L-03513-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 1,550 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
